CCDI case PBCKYW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx.
https://portal.gdc.cancer.gov/cases/f4a2d26a-4a55-4f62-836a-0c7178115972

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mucoepidermoid carcinoma: ICD-O-3 morphology code: 8430/3; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 1.9 years (694 days).

Biospecimens (3 samples)
- Sample 0DVBVD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBVM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVBVQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
